Somatic mutation profile of tumor specimen ALCH-B48G-TTP1-A (aliquot ALCH-B48G-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B48G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.9 years (27,708 days).
Specimen ALCH-B48G-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cf773a1-09c1-4a96-8b42-cdeb27f12ee9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B48G-NB1-A (Blood Derived Normal), aliquot ALCH-B48G-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7ff1e88-66bd-4adf-a455-8f4d43400dc1

The open-access MAF lists 157 somatic variants for this specimen: 104 protein-altering or splice-affecting, 28 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 28, Intron 13, Nonsense Mutation 6, Splice Site 4, 3'UTR 3, 5'UTR 3, RNA 3, 3'Flank 2, Frame Shift Del 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 57/216 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANK1 | c.733A>T p.I245F | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV55873989; called by muse, mutect2, varscan2
- CACNA1C | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV100221142; called by muse, mutect2, varscan2
- CCNB3 | c.2761A>G p.I921V | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs782396691; called by muse, mutect2
- COL27A1 | c.3256C>A p.P1086T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.098); catalogued as COSV61930183; called by muse, mutect2, varscan2
- CSNK1A1L | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as COSV65789464; called by muse, mutect2
- CYP11B1 | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99455748; called by muse, mutect2
- DCLK3 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs369306232, COSV69364245; called by muse, mutect2
- DMXL1 | c.5812G>A p.G1938S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs144486951; called by muse, mutect2
- EEFSEC | c.525-1G>C p.X175_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | catalogued as COSV54632821; called by muse, mutect2
- EEFSEC | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV54628136; called by muse, mutect2
- GPM6A | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as rs867058508, COSV54540095; called by muse, mutect2
- GRPR | c.1086G>T p.K362N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV66669905; called by muse, mutect2, varscan2
- LRFN5 | c.416C>A p.S139Y | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV53243984; called by muse, mutect2, varscan2
- MAGEA11 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV100290429; called by muse, varscan2
- MDH2 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1554584456; called by muse, mutect2
- MEPE | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs760099024; called by muse, mutect2, varscan2
- MFSD3 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs1381143041; called by muse, mutect2, varscan2
- MROH8 | c.1795G>T p.V599L | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1212943514; called by muse, mutect2, varscan2
- OR6N2 | c.926G>C p.G309A | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.058); catalogued as COSV100210605, COSV59410101; called by muse, mutect2
- PCDH7 | c.3082A>G p.N1028D | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1188323113; called by muse, mutect2
- PPFIBP1 | c.2803G>T p.G935* (on ENST00000318304 / NM_177444.3; = p.G929* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 9/103 reads (9%) | catalogued as COSV99944504; called by muse, mutect2
- PSG7 | c.1023C>A p.F341L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV68447032; called by muse, mutect2, varscan2
- RIPK4 | c.1051G>T p.V351L (on ENST00000352483; = p.V303L on NM_020639.3) | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV60187206; called by muse, mutect2, varscan2
- SERTAD4 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 8/156 reads (5%) | catalogued as COSV65399844; called by muse, mutect2
- SETX | c.4199G>C p.G1400A | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56391731; called by muse, mutect2
- SHISA9 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.091); catalogued as COSV69644591; called by muse, mutect2, varscan2
- SPANXN4 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100980992; called by muse, mutect2
- TENM1 | c.2766T>A p.D922E | Missense Mutation (SNP) | VAF 31/352 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV64433153; called by muse, mutect2
- TENM2 | c.2180C>G p.P727R (on ENST00000518659 / NM_001122679.2; = p.P495R on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.511); catalogued as COSV69135684; called by muse, mutect2
- TET1 | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV101019039; called by muse, mutect2
- THBS2 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.157); catalogued as COSV64677405; called by muse, mutect2
- TMEM229B | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs775807942; called by mutect2, varscan2
- VPS16 | c.1897C>T p.H633Y | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1188681613; called by muse, mutect2, varscan2
- ZNF185 | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs782020983; called by muse, mutect2
- ZNF585A | c.1162G>T p.G388W (on ENST00000292841 / NM_001288800.2; = p.G333W on NM_152655.3) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53066119; called by muse, mutect2
- ZNF616 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100348646; called by muse, mutect2, varscan2
- ADAM30 | c.1684G>T p.V562F | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AFF4 | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- AMER3 | c.2383C>A p.P795T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ANKMY2 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- ANO4 | c.1815C>G p.N605K (on ENST00000392977 / NM_001286615.2; = p.N570K on NM_178826.4) | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); called by muse, mutect2
- BEND2 | c.1389G>T p.Q463H | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- CACNA2D2 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CARD9 | c.1313T>A p.L438H | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- CD163 | c.3376G>T p.A1126S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- CDH17 | c.150+1G>T p.X50_splice | Splice Site (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- CFAP47 | c.8176T>G p.Y2726D | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- CFHR5 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, varscan2
- CLCN7 | c.1618-8T>A | Splice Region (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- CROCC2 | c.3403del p.A1135Pfs*24 | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, varscan2
- CYP21A2 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.009); called by muse, mutect2
- CYP2R1 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- DAOA | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- DCUN1D4 | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2
- DPY19L3 | c.2117C>T p.T706I | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG4 | c.2670C>A p.F890L | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- EGFLAM | c.479T>A p.L160Q | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- EGFLAM | c.1402C>A p.L468I | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.327); called by muse, mutect2
- ENPP2 | c.1699T>C p.C567R (on ENST00000075322 / NM_001040092.3; = p.C619R on NM_006209.5) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ESS2 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- FAM187A | c.202C>G p.Q68E | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- FAM47B | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- FER1L6 | c.509C>A p.T170N | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GABRQ | c.1208C>G p.P403R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- HECW2 | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPB3 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- IGKV1-16 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.195); called by muse, mutect2
- IPO9 | c.3079C>T p.H1027Y | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- IWS1 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- KIAA1841 | c.2078T>C p.V693A | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2
- LILRA2 | c.189A>T p.E63D | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2
- LIN7C | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- MAGEA12 | c.596C>A p.T199K | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2
- MAGED2 | c.846+1G>T p.X282_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- MAN2A2 | c.1691G>C p.G564A | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); called by muse, mutect2
- MKX | c.536A>T p.E179V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, varscan2
- MMP3 | c.1070-1G>C p.X357_splice | Splice Site (SNP) | VAF 32/221 reads (14%) | called by muse, mutect2, varscan2
- MORN5 | c.203A>C p.Y68S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MSN | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, mutect2
- MYO5B | c.3703G>T p.G1235C | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAPB | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NLRP14 | c.857C>A p.S286Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR5D14 | c.403A>T p.T135S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2
- PGR | c.836G>T p.R279M | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- PHF8 | c.2885C>T p.P962L (on ENST00000357988 / NM_001184896.1; = p.P926L on NM_015107.3) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2
- PPFIBP1 | c.2804G>T p.G935V (on ENST00000318304 / NM_177444.3; = p.G929V on NM_003622.4) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- PPP1R2B | c.571G>T p.G191* | Nonsense Mutation (SNP) | VAF 7/152 reads (5%) | called by muse, mutect2
- PRDM10 | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN11A | c.2227G>T p.V743F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); called by muse, mutect2
- SEC11C | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.278); called by muse, mutect2
- SPEF2 | c.5065G>A p.A1689T | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.011); called by muse, mutect2
- SSH1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SYCE1 | c.702G>C p.Q234H (on ENST00000343131 / NM_001143764.3; = p.Q198H on NM_130784.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TENM2 | c.532A>T p.S178C | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TLE1 | c.1694G>T p.R565L | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TNRC18 | c.6799G>C p.G2267R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNS1 | c.3537G>T p.Q1179H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP27X | c.586A>T p.N196Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- WDTC1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZBP1 | c.1031C>A p.P344Q | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZDBF2 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- ZNF415 | c.1461G>T p.Q487H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ZNF616 | c.2108A>C p.H703P | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ABL2 | c.867C>T p.T289= (on ENST00000502732 / NM_007314.4; = p.T274= on NM_005158.5) | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- ADAT3 | c.729G>T p.V243= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- ATP13A5 | c.627G>T p.V209= | Silent (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.657G>T p.A219= | Silent (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- C8B | c.981G>A p.E327= | Silent (SNP) | VAF 15/328 reads (5%) | called by muse, mutect2
- CFAP47 | c.6951A>G p.Q2317= | Silent (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- CSMD1 | c.6144G>C p.T2048= (on ENST00000520002; = p.T2047= on NM_033225.6) | Silent (SNP) | VAF 30/504 reads (6%) | catalogued as COSV59280209, COSV59291989, COSV59316091; called by muse, mutect2
- DLC1 | c.390C>T p.T130= | Silent (SNP) | VAF 9/155 reads (6%) | called by muse, mutect2
- DOCK9 | c.2007C>T p.F669= (on ENST00000376460 / NM_001366676.2; = p.F670= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/170 reads (5%) | catalogued as rs1462444828; called by muse, mutect2
- FAM126B | c.1239T>A p.T413= | Silent (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- GPRASP1 | c.1833C>T p.P611= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- HCRTR2 | c.454C>A p.R152= | Silent (SNP) | VAF 55/316 reads (17%) | catalogued as COSV63795299; called by muse, mutect2, varscan2
- HEPH | c.1923A>T p.T641= (on ENST00000343002; = p.T374= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/248 reads (8%) | called by muse, mutect2
- HLA-DPB1 | c.15G>A p.Q5= | Silent (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- LAMB4 | c.1485C>A p.G495= | Silent (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- MXRA5 | c.6726G>T p.P2242= | Silent (SNP) | VAF 15/273 reads (5%) | catalogued as COSV54253266; called by muse, mutect2
- OR10D3 | c.486C>T p.L162= | Silent (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2
- OR2L13 | c.423G>C p.V141= | Silent (SNP) | VAF 8/241 reads (3%) | catalogued as COSV63554292, COSV63560396; called by muse, mutect2
- PCDH17 | c.1671G>A p.S557= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs746175727, COSV64977233; called by muse, mutect2
- PIEZO2 | c.240G>T p.T80= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs376427770; called by muse, mutect2, varscan2
- PRKX | c.444G>T p.T148= | Silent (SNP) | VAF 28/330 reads (8%) | catalogued as COSV53324044; called by muse, mutect2
- SLC26A4 | c.96C>T p.F32= | Silent (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- TCEA3 | c.847T>C p.L283= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- TECPR2 | c.3690C>T p.A1230= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as rs1008937153; called by muse, mutect2
- TENM2 | c.2181C>A p.P727= (on ENST00000518659 / NM_001122679.2; = p.P495= on NM_001080428.3) | Silent (SNP) | VAF 9/123 reads (7%) | called by muse, mutect2
- TOX2 | c.78C>A p.L26= | Silent (SNP) | VAF 23/175 reads (13%) | called by muse, mutect2, varscan2
- TPP2 | c.3528C>T p.L1176= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- ZSCAN1 | c.978C>A p.G326= | Silent (SNP) | VAF 13/154 reads (8%) | called by muse, mutect2
- AC024940.1 | n.5393A>C | RNA (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.858+103G>T | Intron (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99857260; called by muse, mutect2, varscan2
- ARHGEF11 | c.4511-108G>T | Intron (SNP) | VAF 15/200 reads (8%) | called by muse, mutect2
- ATP6V1B1 | c.119-78G>A | Intron (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- B4GALNT1 | chr12:57622850 C>A | 3'Flank (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622851 A>T | 3'Flank (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2, varscan2
- BCOR | c.87-423G>T | Intron (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- CLK2P1 | n.809A>T | RNA (SNP) | VAF 32/304 reads (11%) | called by muse, mutect2
- COL4A2 | c.648+174G>T | Intron (SNP) | VAF 18/210 reads (9%) | catalogued as COSV64631937; called by muse, mutect2
- CSF1 | c.-56G>C | 5'UTR (SNP) | VAF 4/23 reads (17%) | catalogued as rs1338199048; called by mutect2, varscan2
- CUL5 | c.-33C>T | 5'UTR (SNP) | VAF 6/52 reads (12%) | catalogued as rs1221083979; called by muse, varscan2
- GABRE | c.-13G>T | 5'UTR (SNP) | VAF 12/98 reads (12%) | catalogued as rs1408424628; called by muse, mutect2, varscan2
- GPI | c.804+24G>T | Intron (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- HOXB1 | c.577+74G>T | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- IL10RA | c.*848A>C | 3'UTR (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- KCNU1 | c.2010-16897G>A | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as rs1335213649; called by muse, mutect2, varscan2
- KIF22 | c.1677+10G>C | Intron (SNP) | VAF 12/148 reads (8%) | catalogued as rs374901797; called by muse, mutect2
- LINC01567 | n.207G>T | RNA (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- MYPN | c.*861C>T | 3'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- RAB11FIP5 | c.432-101G>T | Intron (SNP) | VAF 11/95 reads (12%) | catalogued as COSV99241576; called by muse, mutect2, varscan2
- RHBDF1 | c.249-163C>T | Intron (SNP) | VAF 4/41 reads (10%) | called by mutect2, varscan2
- TMPRSS11F | c.1015+2135T>A | Intron (SNP) | VAF 13/172 reads (8%) | called by muse, mutect2
- TNFRSF18 | c.*56C>A | 3'UTR (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- USP6 | c.156-60C>T | Intron (SNP) | VAF 14/116 reads (12%) | catalogued as rs369378215; called by muse, mutect2
- WDR86 | chr7:151412000 del C | 5'Flank (DEL) | VAF 11/88 reads (13%) | called by mutect2, pindel, varscan2
